Gene-level copy-number profile of specimen HCM-BROD-0100-C15-85A from HCMI case HCM-BROD-0100-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 64.4 years (23,514 days).
Specimen HCM-BROD-0100-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8f5be45c-5c92-4a90-90f7-24039ffd1ea4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0100-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,761 have no estimate.
https://portal.gdc.cancer.gov/files/6ef1a650-a880-44dc-9c32-0a9ba3888fd0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,995; copy number 2: 21,441; copy number 3: 19,661; copy number 4: 9,063; copy number 5: 3,374; copy number 6: 2,771; copy number 7: 277; copy number 8: 106; copy number 9: 56; copy number 10: 14; copy number 11: 34; copy number 12: 32; copy number 16: 2; copy number 26: 26; copy number 33: 1; copy number 36: 7; copy number 39: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,702 genes in 82 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,412,576–145,824,095, 32 genes, copy number 5–7 (within-gene range 4–7): RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1, RNVU1-26, RNVU1-2A, RNVU1-28, PPIAL4F, AC242498.1, FAM72D, LINC01145, RNU1-153P, AC241585.2, AC241585.1, PPIAL4D, AC245014.2, RNVU1-14, AC245014.3, AC245014.1, NBPF20, PFN1P3, RNU1-154P, RNVU1-31, AC239860.2, AC239860.1, NBPF25P, GPR89A, PDZK1, CD160, RNF115.
- chr1:145,866,560–147,517,875, 52 genes, copy number 5: ANKRD35, ITGA10, AC243547.1, PEX11B, RBM8A, GNRHR2, LIX1L-AS1, AC243547.3, LIX1L, ANKRD34A, AC243547.2, POLR3GL, TXNIP, HJV, AC239799.2, RNVU1-6, LINC01719, NBPF10, NOTCH2NLA, AC239799.1, RNU6-1071P, NUDT4P2, SEC22B4P, PPIAL4H, RNVU1-29, RNVU1-25, AC245407.1, HYDIN2, RNA5SP536, AC241929.1, NBPF12, PFN1P8, AC244394.3, AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P.
- chr1:147,689,256–148,288,951, 25 genes, copy number 5: RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3.
- chr1:151,281,618–151,459,494, 11 genes, copy number 5 (within-gene range 4–5): ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25.
- chr1:152,510,803–153,070,840, 38 genes, copy number 5: LCE5A, CRCT1, LCE3E, LCE3D, LCE3C, LCE3B, LCE3A, LCEP4, LCEP3, LCE2D, LCE2C, LCE2B, LCE2A, LCE4A, C1orf68, LCEP2, LCEP1, KPRP, LCE1F, LCE1E, LCE1D, LCE1C, LCE1B, LCE1A, LCE6A, SMCP, IVL, LINC01527, SPRR5, SPRR4, SPRR1A, SPRR3, AL356867.2, AL356867.1, SPRR1B, SPRR2D, SPRR2A, SPRR2B.
- chr2:171,317,405–185,833,290, 235 genes, copy number 5–6 (broad region; genes not listed).
- chr2:190,189,735–203,873,965, 239 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:206,443,532–208,920,664, 63 genes, copy number 6 (broad region; genes not listed).
- chr3:16,687,986–18,444,817, 12 genes, copy number 5 (within-gene range 2–5): AC091493.1, CDYLP1, PLCL2, MIR3714, PLCL2-AS1, AC090644.1, TBC1D5, AC090960.1, AC140076.1, RNU7-10P, AC104451.1, AC104451.2.
- chr3:193,144,464–198,123,232, 168 genes, copy number 5–6 (broad region; genes not listed).
- chr5:58,198–12,297,504, 234 genes, copy number 5 (broad region; genes not listed).
- chr5:12,794,100–15,496,353, 30 genes, copy number 5–6 (within-gene range 4–6): AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1.
- chr5:43,192,071–45,895,970, 36 genes, copy number 5–7: NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr5:94,979,151–95,961,851, 19 genes, copy number 5–6: MCTP1-AS1, FAM81B, RTRAFP2, TTC37, RNU6-308P, ARSK, GPR150, RFESD, SPATA9, AC008840.1, RHOBTB3, GLRX, HSPD1P11, GGCTP1, AC008592.3, LINC01554, AC008592.4, AC008592.1, ELL2.
- chr6:137,657,998–138,344,663, 12 genes, copy number 5: AL356234.2, AL356234.1, LINC02539, Y_RNA, WAKMAR2, TNFAIP3, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1.
- chr7:37,032–27,410,358, 467 genes, copy number 5–8 (broad region; genes not listed).
- chr7:38,977,909–80,679,277, 786 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:90,383,721–91,556,848, 12 genes, copy number 5 (within-gene range 4–5): CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1.
- chr8:43,672,823–89,243,793, 624 genes, copy number 5–6 (broad region; genes not listed).
- chr8:89,585,872–145,066,685, 871 genes, copy number 6 (broad region; genes not listed).
- chr9:32,293,558–32,727,522, 13 genes, copy number 5: RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1.
- chr9:35,561,831–36,830,456, 54 genes, copy number 5–6 (within-gene range 4–6): FAM166B, RPS29P17, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24, RNF38, MELK, AL450267.2, MIR4475.
- chr11:85,628,573–87,606,885, 47 genes, copy number 5: TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1, AP000811.1, PSMA2P1, AP003497.1, AP003497.2, AP001784.1, RNU6-1135P.
- chr11:94,493,979–95,497,553, 28 genes, copy number 5: ANKRD49, C11orf97, FUT4, PIWIL4, AP000943.2, AP000943.3, AP000943.1, LINC02700, AMOTL1, AP002383.2, ST13P11, CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1, BUD13P1, AP000787.2, AP000787.1, SESN3, AP000787.3, AP001790.1.
- chr11:102,766,801–111,179,641, 117 genes, copy number 5 (broad region; genes not listed).
- chr13:52,600,042–58,377,774, 44 genes, copy number 5–6: AL137058.2, MRPS31P4, HNRNPA1L2, SUGT1-DT, SUGT1, CNMD, MIR759, PPIAP26, PCDH8, OLFM4, LINC01065, AL136359.1, PCDH8P1, AL356295.1, RN7SL618P, AL450423.1, ZNF646P1, LINC00558, LINC00458, AL356052.1, RPL13AP25, AL390964.1, LINC02335, AL139038.1, MIR5007, AL354821.1, HNF4GP1, SPATA2P1, RN7SKP6, PRR20A, PRR20C, PRR20B, PRR20D, PRR20E, PRR20FP, MTCO2P3, SLC25A5P4, RPL31P53, PCDH17, AL445288.1, RNA5SP30, LINC02338, LINC00374, AL161423.1.
- chr15:85,579,046–89,398,487, 67 genes, copy number 5–9 (broad region; genes not listed).
- chr15:95,990,582–96,327,361, 10 genes, copy number 6 (within-gene range 4–6): AC012409.2, AC024337.1, AC024337.2, NR2F2-AS1, AC012409.5, AC012409.3, AC012409.1, AC012409.4, LINC02157, AC016251.1.
- chr15:97,560,849–98,420,998, 14 genes, copy number 9: AC026523.4, LINC00923, AC024651.2, ARRDC4, AC024651.1, LINC02251, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1, AC015722.2, LINC02351.
- chr16:72,112,157–90,222,851, 457 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:29,424,762–29,707,090, 11 genes, copy number 5–12 (within-gene range 2–12): RNU6-711P, RNU6-1034P, ABHD15, ABHD15-AS1, TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2.
- chr17:36,225,246–36,457,535, 11 genes, copy number 5–9 (within-gene range 5–22): AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, RNU6-1192P, TBC1D3F, TBC1D3J.
- chr17:36,684,754–38,144,287, 38 genes, copy number 16–39: AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526.
- chr17:38,297,023–40,782,550, 121 genes, copy number 5–12 (broad region; genes not listed).
- chr17:49,788,648–50,016,844, 12 genes, copy number 5 (within-gene range 2–5): KAT7, SRP14P3, AC027801.5, TAC4, AC027801.1, AC027801.2, AC027801.4, AC027801.3, RNU6-1313P, DLX4, DLX3, AC009720.1.
- chr17:50,094,065–50,797,651, 47 genes, copy number 5: AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P, COL1A1, AC015909.1, AC015909.4, SUMO2P7, TMEM92, TMEM92-AS1, XYLT2, AC015909.5, MRPL27, EME1, LRRC59, Y_RNA, AC004707.1, ACSF2, MRPS21P9, CHAD, AC021491.4, RSAD1, AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3, AC004590.1, ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.1.
- chr19:27,793,431–29,015,160, 30 genes, copy number 6 (within-gene range 3–6): AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532.
- chr19:33,555,568–36,125,947, 144 genes, copy number 5–7 (broad region; genes not listed).
- chr20:87,250–13,996,443, 277 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:20,389,530–64,327,972, 1,019 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 608. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
